Somatic mutation profile of tumor specimen 0DW42I from CCDI case PBCNMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.4 years (4,877 days).
Specimen 0DW42I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20b50008-215c-426d-b272-d6494c72368a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1802169c-0a24-4e33-9380-2291816395b8

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 50/444 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.529_546del p.P177_C182del | In Frame Del (DEL) | VAF 50/290 reads (17%) | hotspot (GDC flag); called by mutect2, varscan2
- CLU | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 52/682 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs759710165; called by muse, mutect2
- PDE8B | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.18); catalogued as COSV99366814; called by muse, mutect2
- SIVA1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs1339465684; called by muse, mutect2, varscan2
- KAT6A | c.4614A>G p.V1538= | Silent (SNP) | VAF 31/548 reads (6%) | catalogued as COSV55904611; called by muse, mutect2
- IGFN1 | c.1242-1716G>A | Intron (SNP) | VAF 45/445 reads (10%) | called by muse, mutect2, varscan2
